Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3365, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3365-01A (Primary Tumor).

Result Name Results Units
☒ Surgical Pathology COPY TO:

COPY TO:

Pre-Op Diagnosis

Right renal mass

Post-Op Diagnosis

Same as above

Clinical History

Nothing indicated

Gross Description:

Received in a single container labeled [REDACTED] right kidney" is a 600 gram partially sectioned right nephrectomy specimen surrounded by a large amount of perinephric adipose tissue and faced anteriorly by a moderate amount of Gerota's fascia. The specimen on reconstruction measures 19.8 x 13.2 x 6.6 cm. The margins of resection include 0.9 cm of grossly patent renal artery, 0.8 cm of grossly patent renal vein and 7.5 cm of grossly patent ureter. The capsule strips with ease to reveal an organ measuring 9.3 x 6.0 x 4.8 cm. The cortex is up to 1.0 cm and is homogeneous and red brown. The corticomedullary junction is poorly defined. The medulla is homogeneous red brown with sharp papillae. The calices and pelvis are lined by smooth gray tan mucosa extending into the ureter. Noted on the anterior aspect in the upper to mid pole is a well circumscribed apparently unencapsulated 3.0 x 3.0 x 2.5 cm focally hemorrhagic for hyalinized tan pink to yellow nodular lesion. A discrete gross capsule is not identified. The lesion extends anteriorly, but appears to be limited by an intact area of attenuated cortical parenchyma. The lesion grossly appears to compress adjacent structures but does not grossly appear to extend into them. No other gross lesions are identified. also received in the same container are three tissue cassettes each labeled [REDACTED]. Representative sections are submitted labeled as follows: A - vascular and ureteral margin; B-F - representative lesion and surrounding tissue; G - random uninvolved parenchyma.

Microscopic Description:

The slides labeled [REDACTED] are examined. See diagnosis.

Final Diagnosis

Right kidney (nephrectomy):

Tumor characteristics:

1. Histologic type: Conventional (clear cell) renal carcinoma
2. Tumor site: Upper to mid pole of right kidney
3. Size: 3.0 x 3.0 x 2.5 cm
4. Macroscopic extent of tumor: Tumor limited to kidney
5. Nuclear grade: Fuhrman grade 2-3
6. Lymphovascular space invasion: No unequivocal lymphovascular space invasion identified
7. Transcapsular extension of tumor: No
8. Renal vein invasion: No
9. Vena caval invasion: Not resected
10. Adrenal gland: Not resected

Surgical margin status:

1. Soft tissue margin: Negative
2. Ureteral margin: Negative
3. Vascular margin: Negative

Lymph node status:

No lymph nodes resected.

Other findings:

Interstitial chronic inflammation.

TNM staging:

pT1a, Nx, Mx PAS 9 SPC-A

CPT: 88307

Source: NCI Genomic Data Commons file e4afe5ca-b821-481f-9bd6-e8b9be11e260 (TCGA-A3-3365.19D68702-18B3-4B80-ADE7-BAA96E4E031A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).